Somatic mutation profile of tumor specimen MP2PRT-PARPYH-TMP1-A (aliquot MP2PRT-PARPYH-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARPYH, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Precursor cell lymphoblastic leukemia, not phenotyped; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.8 years (2,105 days).
Specimen MP2PRT-PARPYH-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f6c8d36-59a1-450d-8038-834442fadffb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPYH-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPYH-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3198301d-9e37-4b35-98b2-b4390109eaa9

The open-access MAF lists 122 somatic variants for this specimen: 90 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 28, Nonsense Mutation 10, Splice Site 2, Intron 2, In Frame Ins 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 30/598 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2
- APOB | c.3233G>C p.R1078T | Missense Mutation (SNP) | VAF 34/605 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV51925462; called by muse, mutect2
- CELSR3 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 134/531 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs144228630; called by muse, mutect2, varscan2
- CHMP7 | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as rs1466269607; called by muse, mutect2, varscan2
- DLG5 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 147/857 reads (17%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); catalogued as COSV64950275; called by muse, mutect2, varscan2
- DSCAML1 | c.1220G>A p.R407H (on ENST00000321322; = p.R347H on NM_020693.4) | Missense Mutation (SNP) | VAF 114/442 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.765); catalogued as rs759795586, COSV58392501; called by muse, mutect2, varscan2
- DZIP1L | c.2140C>G p.Q714E | Missense Mutation (SNP) | VAF 26/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100551386, COSV59523777; called by muse, mutect2
- EPGN | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs377708890; called by muse, mutect2, varscan2
- ERAL1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 85/555 reads (15%) | catalogued as COSV99650422; called by muse, mutect2, varscan2
- ERG | c.401T>A p.V134E | Missense Mutation (SNP) | VAF 167/366 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55737982; called by muse, mutect2, varscan2
- FAT4 | c.5865G>C p.E1955D | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100627164; called by muse, mutect2, varscan2
- GUCY2F | c.2716G>A p.V906M | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763367582; called by muse, mutect2, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 102/473 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- IGF1R | c.2752G>C p.D918H | Missense Mutation (SNP) | VAF 76/447 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51305902, COSV51357250; called by muse, mutect2, varscan2
- KATNAL2 | c.1586C>G p.S529* (on ENST00000356157 / NM_001353899.1; = p.S457* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 81/348 reads (23%) | catalogued as COSV55298604; called by muse, mutect2, varscan2
- KCNC3 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 137/623 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766890044; called by muse, mutect2, varscan2
- KDM5C | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64772335; called by muse, mutect2, varscan2
- KIAA1755 | c.3286G>C p.D1096H | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV54076586, COSV99642648; called by muse, mutect2, varscan2
- LDHD | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 48/900 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as rs757955968; called by muse, mutect2
- MED12L | c.3088G>A p.D1030N | Missense Mutation (SNP) | VAF 42/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768404628, COSV56368658, COSV56370540; called by muse, mutect2, varscan2
- MGAT4C | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153028; called by muse, mutect2
- MROH1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 27/774 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV58190790; called by muse, mutect2
- MUC16 | c.4065G>C p.K1355N | Missense Mutation (SNP) | VAF 104/399 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV67458417; called by muse, mutect2, varscan2
- OR1L1 | c.1062G>T p.M354I (on ENST00000373686; = p.M304I on NM_001005236.3) | Missense Mutation (SNP) | VAF 47/244 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV58936413; called by muse, mutect2, varscan2
- OR2M5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 89/195 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs147580819; called by muse, mutect2, varscan2
- PABPC4L | c.1056G>A p.M352I | Missense Mutation (SNP) | VAF 35/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69931176, COSV99081465; called by muse, mutect2
- PCDHB15 | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); catalogued as rs1272131176, COSV50862616; called by muse, mutect2
- PCNX3 | c.6005C>T p.P2002L | Missense Mutation (SNP) | VAF 31/755 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1287183492; called by muse, mutect2
- PDE1C | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 61/473 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.898); catalogued as rs1161033445; called by muse, mutect2, varscan2
- RCOR1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs1334393631, COSV51767401; called by muse, mutect2, varscan2
- RPL10A | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 94/490 reads (19%) | catalogued as COSV57689384; called by muse, mutect2, varscan2
- TECTA | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV50688513; called by muse, mutect2
- TG | c.2630G>C p.S877T | Missense Mutation (SNP) | VAF 42/567 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as COSV55092373; called by muse, mutect2
- TGM6 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.389); catalogued as rs769042038, COSV99171718; called by muse, varscan2
- TRAPPC12 | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as COSV60846970; called by muse, mutect2
- TTN | c.36832G>A p.D12278N (on ENST00000591111; = p.D4854N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/454 reads (3%) | PolyPhen benign (0.029); catalogued as COSV59986509; called by muse, mutect2
- UNCX | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 209/503 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310234; called by muse, mutect2, varscan2
- USP51 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 65/246 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV72351629, COSV72351917; called by muse, mutect2, varscan2
- VIPR2 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 38/761 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs1207352245, COSV51105648; called by muse, mutect2
- ZNF462 | c.5071G>A p.E1691K | Missense Mutation (SNP) | VAF 168/731 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV52952548; called by muse, mutect2, varscan2
- A2M | c.2042C>G p.S681* | Nonsense Mutation (SNP) | VAF 32/338 reads (9%) | called by muse, mutect2
- AC098582.1 | c.324G>T p.W108C | Missense Mutation (SNP) | VAF 107/483 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ALDH18A1 | c.1574C>G p.S525* | Nonsense Mutation (SNP) | VAF 51/368 reads (14%) | called by muse, mutect2, varscan2
- ALPK3 | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 176/790 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); called by muse, mutect2
- ALPK3 | c.758G>C p.G253A | Missense Mutation (SNP) | VAF 194/766 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2
- ALPK3 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ALPK3 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 143/641 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF4 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 183/897 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARNT2 | c.1971G>A p.W657* | Nonsense Mutation (SNP) | VAF 250/672 reads (37%) | called by muse, mutect2
- C7orf33 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 129/582 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CCDC168 | c.5260G>C p.D1754H | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CCDC191 | c.19G>A p.G7R | Missense Mutation (SNP) | VAF 76/382 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CMYA5 | c.8032G>C p.E2678Q | Missense Mutation (SNP) | VAF 83/489 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- COG5 | c.1940G>C p.R647T (on ENST00000347053 / NM_001379512.1; = p.R668T on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/469 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CPSF2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- EAF2 | c.106_106+2del p.X36_splice | Splice Site (DEL) | VAF 109/610 reads (18%) | called by mutect2, pindel*
- ENTPD8 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 92/587 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM118B | c.697-1G>C p.X233_splice | Splice Site (SNP) | VAF 14/236 reads (6%) | called by muse, mutect2
- FAM160A1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 105/540 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- FGD6 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRB1 | c.720G>C p.K240N | Missense Mutation (SNP) | VAF 55/464 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GCC2 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 43/282 reads (15%) | called by muse, mutect2, varscan2
- HEATR9 | c.392C>G p.S131C | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.338); called by muse, mutect2
- IGKV3-15 | c.344_345insCCC p.P115dup | In Frame Ins (INS) | VAF 51/66 reads (77%) | called by mutect2, pindel, varscan2
- ITIH2 | c.1955C>G p.S652* | Nonsense Mutation (SNP) | VAF 159/317 reads (50%) | called by muse, mutect2, varscan2
- KIAA1549 | c.3294C>G p.I1098M | Missense Mutation (SNP) | VAF 24/450 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- KMT2C | c.6878C>T p.S2293F | Missense Mutation (SNP) | VAF 111/504 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MVD | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 36/864 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MYBL2 | c.1988G>A p.W663* | Nonsense Mutation (SNP) | VAF 13/499 reads (3%) | called by muse, mutect2
- NFATC2 | c.2011C>G p.Q671E | Missense Mutation (SNP) | VAF 38/319 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NKX1-1 | c.623G>C p.R208P | Missense Mutation (SNP) | VAF 233/891 reads (26%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- NRXN2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 161/548 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- OR1C1 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCNX3 | c.5840C>G p.S1947C | Missense Mutation (SNP) | VAF 35/826 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2
- PDLIM5 | c.1482G>C p.L494F | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R42 | c.539T>A p.L180H | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PSG3 | c.616G>T p.G206C | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- RADIL | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 357/1036 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- REPIN1 | c.1230G>C p.K410N | Missense Mutation (SNP) | VAF 163/1082 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCART1 | c.188C>G p.S63C | Missense Mutation (SNP) | VAF 50/824 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SNAPC4 | c.4271C>G p.T1424R | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2
- SPATC1L | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 46/1004 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- STON2 | c.1999G>C p.E667Q (on ENST00000649389 / NM_001366849.2; = p.E610Q on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/524 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SYCP2 | c.3326C>A p.P1109Q | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- TCTE1 | c.264C>G p.I88M | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TCTE1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 89/538 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TLR3 | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 96/456 reads (21%) | called by muse, mutect2, varscan2
- TMEM71 | c.670C>G p.H224D (on ENST00000523829 / NM_001382398.1; = p.H205D on NM_144649.3) | Missense Mutation (SNP) | VAF 36/291 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- WNT9B | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 133/969 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.767G>A p.R256K | Missense Mutation (SNP) | VAF 74/558 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ACSL6 | c.585C>T p.I195= (on ENST00000379240; = p.I220= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/363 reads (8%) | called by muse, mutect2
- ADCY2 | c.2682G>A p.P894= | Silent (SNP) | VAF 89/466 reads (19%) | catalogued as rs201615098; called by muse, mutect2, varscan2
- AGO1 | c.2193G>A p.G731= | Silent (SNP) | VAF 82/365 reads (22%) | called by muse, mutect2, varscan2
- AK4 | c.177G>A p.E59= | Silent (SNP) | VAF 46/384 reads (12%) | called by muse, mutect2, varscan2
- BCL11A | c.357A>T p.G119= | Silent (SNP) | VAF 18/484 reads (4%) | called by muse, mutect2
- CAD | c.579C>G p.L193= | Silent (SNP) | VAF 56/469 reads (12%) | catalogued as COSV99255266; called by muse, mutect2, varscan2
- CFAP46 | c.1959C>T p.F653= | Silent (SNP) | VAF 33/630 reads (5%) | catalogued as rs1288808475, COSV63950758; called by muse, mutect2
- DCAF1 | c.4410C>T p.D1470= | Silent (SNP) | VAF 129/320 reads (40%) | catalogued as rs370422608; called by muse, mutect2, varscan2
- DNAH1 | c.10482G>A p.L3494= | Silent (SNP) | VAF 34/386 reads (9%) | called by muse, mutect2
- DRD1 | c.1287C>T p.D429= | Silent (SNP) | VAF 41/448 reads (9%) | catalogued as rs200809329; called by muse, mutect2
- FGFR2 | c.2316C>T p.L772= | Silent (SNP) | VAF 64/526 reads (12%) | called by muse, mutect2, varscan2
- GLRX3 | c.291C>T p.I97= | Silent (SNP) | VAF 64/299 reads (21%) | catalogued as rs748966258, COSV58694626; called by muse, mutect2, varscan2
- IGKV1D-37 | chr2:89885215 del C | Silent (DEL) | VAF 22/38 reads (58%) | called by mutect2, varscan2
- KIAA1755 | c.3072G>C p.L1024= | Silent (SNP) | VAF 79/565 reads (14%) | called by muse, mutect2, varscan2
- LYRM4 | c.243G>A p.L81= | Silent (SNP) | VAF 65/427 reads (15%) | called by muse, mutect2, varscan2
- NKX1-1 | c.852G>A p.R284= | Silent (SNP) | VAF 213/924 reads (23%) | called by muse, mutect2, varscan2
- PANK4 | c.729G>C p.S243= | Silent (SNP) | VAF 34/732 reads (5%) | called by muse, mutect2
- PDZRN3 | c.639G>C p.A213= | Silent (SNP) | VAF 376/836 reads (45%) | called by muse, mutect2, varscan2
- PLB1 | c.756G>T p.V252= | Silent (SNP) | VAF 95/478 reads (20%) | called by muse, mutect2, varscan2
- POLDIP2 | c.690C>G p.L230= | Silent (SNP) | VAF 51/397 reads (13%) | called by muse, mutect2, varscan2
- PRMT6 | c.81G>A p.A27= | Silent (SNP) | VAF 172/753 reads (23%) | catalogued as COSV63655090; called by muse, mutect2, varscan2
- RAB44 | c.930G>A p.E310= | Silent (SNP) | VAF 43/914 reads (5%) | called by muse, mutect2
- SPHK2 | c.1095C>T p.G365= | Silent (SNP) | VAF 41/838 reads (5%) | catalogued as rs781767000; called by muse, mutect2
- VPS29 | c.147C>G p.L49= | Silent (SNP) | VAF 58/326 reads (18%) | catalogued as rs776447100; called by muse, mutect2, varscan2
- VWA2 | c.1749C>T p.F583= | Silent (SNP) | VAF 90/655 reads (14%) | catalogued as rs143465186; called by muse, mutect2, varscan2
- ZDHHC11 | c.816C>G p.L272= | Silent (SNP) | VAF 19/444 reads (4%) | catalogued as COSV52066008, COSV52070000, COSV99363788; called by muse, mutect2
- ZNF385C | c.414G>A p.Q138= | Silent (SNP) | VAF 22/330 reads (7%) | called by muse, mutect2
- ZNF628 | c.540C>G p.V180= | Silent (SNP) | VAF 177/722 reads (25%) | catalogued as rs747080941; called by muse, mutect2, varscan2
- CCDC180 | c.-94G>C | 5'UTR (SNP) | VAF 116/544 reads (21%) | catalogued as COSV63827144; called by muse, mutect2, varscan2
- CMTM1 | c.81+94C>T | Intron (SNP) | VAF 456/983 reads (46%) | catalogued as rs774917241, COSV99862677; called by muse, mutect2, varscan2
- CPLANE1 | c.*4622G>C | 3'UTR (SNP) | VAF 18/527 reads (3%) | catalogued as COSV57055825; called by muse, mutect2
- UNC13B | c.761+4819G>A | Intron (SNP) | VAF 48/280 reads (17%) | catalogued as rs1006026340; called by muse, mutect2, varscan2
